Gene-level copy-number profile of tumor specimen ALCH-B2S6-TTP1-A from ALCHEMIST case ALCH-B2S6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 68.9 years (25,149 days).
Specimen ALCH-B2S6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b866a573-5e69-4041-a616-3a68edb38cb1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2S6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,261 have no estimate.
https://portal.gdc.cancer.gov/files/0c1c3215-79e2-4020-9383-ea02669cc301

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 23,254; copy number 2: 32,382; copy number 3: 2,644; copy number 4: 68.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:55,602,360–55,686,160, 7 genes: OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1.
- chr11:117,015,897–117,036,051, 2 genes (within-gene range 0–1): RNY4P6, AP000936.3.
- chr17:40,624,962–40,689,360, 5 genes: SMARCE1, AC073508.2, AC073508.3, KRT222, AC073508.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 23,246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
